Gene-level copy-number profile of tumor specimen TCGA-VQ-A8P3-01A from TCGA case TCGA-VQ-A8P3, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 72.8 years (26,582 days).
Specimen TCGA-VQ-A8P3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.254cffc3-5757-4a18-b2d8-60114d022c9d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8P3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4cc2122-f9e5-4fb5-ab0c-4a1f462b5fbf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 139; copy number 1: 3,110; copy number 2: 56,162; copy number 3: 27; copy number 4: 370.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8P3-01A-11D-A363-01): tumor purity 0.57, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 134 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:178,006,136–178,093,984, 3 genes (within-gene range 0–1): CRYZL2P, AL359075.1, RASAL2-AS1.
- chr1:178,194,342–178,194,709, 1 gene: AL160281.1.
- chr1:204,218,853–204,377,665, 4 genes (within-gene range 0–2): PLEKHA6, AL592114.3, AL592114.1, LINC00628.
- chr2:186,590,056–186,680,901, 1 gene (within-gene range 0–2): ITGAV.
- chr2:240,565,804–240,631,259, 4 genes (within-gene range 0–2): RNPEPL1, CAPN10-DT, CAPN10, GPR35.
- chr2:241,227,264–241,354,027, 4 genes (within-gene range 0–2): HDLBP, SEPTIN2, AC104841.1, AC005104.1.
- chr2:241,360,891–241,372,749, 1 gene: AC005104.2.
- chr3:49,907,160–50,100,045, 2 genes (within-gene range 0–2): MON1A, RBM6.
- chr5:524,109–892,801, 12 genes: AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9.
- chr5:59,039,761–59,063,503, 1 gene: AC092343.1.
- chr6:1,623,806–2,245,605, 2 genes: GMDS, AL035693.1.
- chr6:26,026,815–26,199,293, 21 genes (within-gene range 0–1): H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4.
- chr6:148,272,304–148,552,048, 2 genes (within-gene range 0–2): SASH1, RNU6-1222P.
- chr7:102,153,355–102,194,164, 5 genes: AC005086.2, AC005086.5, AC005086.4, AC005086.3, AC005086.1.
- chr7:157,854,529–157,869,154, 2 genes: PTPRN2-AS1, AC011899.2.
- chr8:140,094,894–140,100,543, 1 gene: PEG13.
- chr10:72,501,746–72,887,694, 11 genes (within-gene range 0–2): AL513185.1, AL513185.2, RN7SL840P, HMGN2P34, AL513185.3, Y_RNA, MCU, MIR4676, AC016542.3, AC016542.2, AC016542.1.
- chr10:75,430,571–75,431,588, 1 gene: AC010997.2.
- chr10:75,450,081–75,643,106, 4 genes: AC010997.6, MIR606, AL589863.2, AL589863.1.
- chr11:2,444,684–2,849,105, 7 genes (within-gene range 0–2): KCNQ1, KCNQ1OT1, AC021424.1, AC021424.3, AC021424.4, AC021424.2, COX6CP18.
- chr11:64,103,188–64,204,543, 3 genes: FLRT1, AP006333.1, STIP1.
- chr15:58,865,175–59,097,419, 1 gene (within-gene range 0–1): RNF111.
- chr15:58,967,046–59,050,385, 2 genes: AC025918.2, AC092757.1.
- chr16:188,969–352,723, 8 genes (within-gene range 0–2): LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2, AXIN1.
- chr16:78,872,739–79,017,429, 6 genes: AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4.
- chr16:89,267,630–89,490,561, 1 gene (within-gene range 0–2): ANKRD11.
- chr16:89,420,075–89,557,766, 6 genes (within-gene range 0–2): AC092120.1, AC092120.3, RNU6-430P, AC092120.2, SPG7, AC092123.1.
- chr20:14,884,250–15,280,873, 5 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.
- chr21:36,156,782–36,294,274, 2 genes (within-gene range 0–2): DOP1B, RPL3P1.
- chr22:28,772,674–29,057,488, 8 genes (within-gene range 0–2): CCDC117, XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1.
- chr22:46,360,834–46,548,196, 3 genes (within-gene range 0–2): CELSR1, AL031597.1, AL021392.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 701. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
